Somatic mutation profile of tumor specimen C3L-05317-54 (aliquot CPT0340740002) from CPTAC case C3L-05317, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 47.7 years (17,416 days).
Specimen C3L-05317-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 021d4c0d-1483-4264-852b-a03d7551476f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05317-50 (Buccal Cell Normal), aliquot CPT0340710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/211fccfe-a622-428d-8613-cd6a806f51b3

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Silent 1, Frame Shift Ins 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 22/76 reads (29%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GK2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.189); catalogued as COSV62626410; called by muse, mutect2, varscan2
- PATZ1 | c.1493G>A p.S498N | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TRPC7 | c.1810T>A p.Y604N | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- UPF2 | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.213); called by muse, mutect2
- NGLY1 | c.696G>A p.E232= | Silent (SNP) | VAF 66/141 reads (47%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.735C>T | RNA (SNP) | VAF 22/70 reads (31%) | catalogued as rs771710827; called by muse, mutect2, varscan2
- BACE1 | chr11:117316453 G>A | 5'Flank (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- MAGI3 | c.1077-1191G>A | Intron (SNP) | VAF 32/80 reads (40%) | catalogued as rs779059199; called by muse, mutect2, varscan2
